Somatic mutation profile of tumor specimen MMRF_2772_1_BM_CD138pos (aliquot MMRF_2772_1_BM_CD138pos_T1_KHS5U_L15722) from MMRF case MMRF_2772, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.0 years (18,643 days).
Specimen MMRF_2772_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a700348-2a9a-423f-90c6-cbe83fb62fc0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2772_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2772_1_PB_WBC_C3_KHS5U_L15766; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20fcfea9-f2df-4907-b1b6-5dd26892c7b5

The open-access MAF lists 110 somatic variants for this specimen: 39 protein-altering or splice-affecting, 14 silent, 57 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 37, Missense Mutation 32, Silent 14, Intron 11, 5'UTR 5, Nonsense Mutation 3, Splice Site 2, 5'Flank 2, Frame Shift Del 2, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 18/96 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 66/531 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADNP2 | c.727T>A p.L243M | Missense Mutation (SNP) | VAF 43/268 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs749064036; called by muse, mutect2, varscan2
- ARID2 | c.2134G>T p.E712* | Nonsense Mutation (SNP) | VAF 26/298 reads (9%) | catalogued as COSV57597758; called by muse, mutect2
- ASB5 | c.515C>T p.T172M | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs545829322, COSV56668638; called by muse, mutect2, varscan2
- C9orf50 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 45/340 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.258); catalogued as rs781474219; called by muse, varscan2
- CCND1 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 48/86 reads (56%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs772857967, COSV57121871; called by muse, varscan2
- CCND1 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 47/87 reads (54%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV57122832; called by muse, varscan2
- CCND1 | c.136A>G p.K46E | Missense Mutation (SNP) | VAF 88/167 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.075); catalogued as rs747665638, COSV57121092; called by muse, mutect2, varscan2
- DMD | c.8862G>C p.E2954D | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100628851; called by muse, mutect2, varscan2
- DOCK2 | c.3659A>G p.Y1220C | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1183186367, COSV56944674; called by muse, mutect2, varscan2
- ENPP1 | c.1092-1G>A p.X364_splice | Splice Site (SNP) | VAF 6/65 reads (9%) | catalogued as COSV62936770; called by muse, mutect2, varscan2
- GLI3 | c.3390C>A p.D1130E | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as COSV67885638; called by muse, mutect2
- IGHJ6 | c.49A>C p.T17P | Missense Mutation (SNP) | VAF 20/46 reads (43%) | PolyPhen probably damaging (0.965); catalogued as rs377341021; called by muse, varscan2
- KALRN | c.5326C>T p.R1776C (on ENST00000360013 / NM_001024660.4; = p.R79C on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1241849175, COSV52254081; called by muse, mutect2, varscan2
- PAN3 | c.1442G>A p.S481N | Missense Mutation (SNP) | VAF 14/394 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.188); catalogued as rs1392778782; called by muse, mutect2
- RGS12 | c.2678G>A p.R893Q | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as rs754718948, COSV100122858; called by muse, mutect2
- ZBTB49 | c.1720C>T p.R574C | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs777886810, COSV61924217; called by muse, mutect2, varscan2
- AVPI1 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 51/101 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- BAG1 | c.623G>T p.G208V | Missense Mutation (SNP) | VAF 53/316 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRD4 | c.3256C>T p.Q1086* | Nonsense Mutation (SNP) | VAF 14/186 reads (8%) | called by muse, mutect2
- C2CD6 | c.517-1G>T p.X173_splice | Splice Site (SNP) | VAF 12/75 reads (16%) | called by muse, mutect2, varscan2
- CCDC14 | c.1465T>A p.L489M (on ENST00000488653; = p.L441M on NM_022757.5) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- CCDC168 | c.12425C>A p.T4142K | Missense Mutation (SNP) | VAF 16/279 reads (6%) | SIFT tolerated (0.92); PolyPhen possibly damaging (0.842); called by muse, mutect2
- CTSV | c.17T>C p.V6A | Missense Mutation (SNP) | VAF 19/490 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2
- EEF2 | c.2543T>C p.I848T | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EYS | c.1748A>T p.D583V | Missense Mutation (SNP) | VAF 39/254 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- IGHJ6 | c.39del p.T14Pfs*? | Frame Shift Del (DEL) | VAF 22/44 reads (50%) | called by pindel, varscan2
- INSYN2A | c.1228T>A p.C410S | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LCLAT1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- MBD3 | c.662C>T p.T221I | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2
- NAV3 | c.5162del p.K1721Sfs*38 | Frame Shift Del (DEL) | VAF 36/227 reads (16%) | called by mutect2, pindel, varscan2
- NELL1 | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- PLXNA1 | c.1465G>A p.D489N | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2
- SMC3 | c.29G>A p.G10D | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ST14 | c.1055A>G p.N352S | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TBC1D32 | c.1465G>T p.E489* | Nonsense Mutation (SNP) | VAF 6/63 reads (10%) | called by muse, mutect2
- TDRD15 | c.4410A>T p.K1470N | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TTC6 | c.197T>G p.V66G (on ENST00000267368; = p.V1335G on NM_001310135.3) | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ABCA12 | c.4543C>A p.R1515= (on ENST00000272895 / NM_173076.3; = p.R1197= on NM_015657.3) | Silent (SNP) | VAF 14/97 reads (14%) | catalogued as CM110697; called by muse, mutect2, varscan2
- ANK1 | c.4011A>G p.G1337= | Silent (SNP) | VAF 21/265 reads (8%) | called by muse, mutect2
- C1orf68 | c.12G>A p.Q4= | Silent (SNP) | VAF 21/514 reads (4%) | called by muse, mutect2
- C9orf40 | c.282A>G p.T94= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as rs777991430, COSV100964967; called by muse, mutect2, varscan2
- CCND1 | c.273G>A p.L91= | Silent (SNP) | VAF 87/176 reads (49%) | called by muse, mutect2, varscan2
- CPAMD8 | c.3201C>T p.P1067= (on ENST00000651564; = p.P1020= on NM_015692.5) | Silent (SNP) | VAF 44/97 reads (45%) | catalogued as rs373988558, COSV101488346; called by muse, mutect2, varscan2
- EDEM1 | c.60A>C p.V20= | Silent (SNP) | VAF 34/84 reads (40%) | called by muse, varscan2
- KLHDC7A | c.1749G>A p.R583= | Silent (SNP) | VAF 57/327 reads (17%) | catalogued as rs1215876120, COSV101272723; called by muse, mutect2, varscan2
- LAMA4 | c.573A>C p.G191= | Silent (SNP) | VAF 33/169 reads (20%) | called by muse, mutect2, varscan2
- PCDHGA8 | c.681C>A p.R227= | Silent (SNP) | VAF 61/346 reads (18%) | called by muse, mutect2, varscan2
- PEAR1 | c.840C>T p.N280= | Silent (SNP) | VAF 98/295 reads (33%) | catalogued as rs143433576; called by muse, mutect2, varscan2
- SART1 | c.969C>T p.D323= | Silent (SNP) | VAF 38/112 reads (34%) | catalogued as rs202095327; called by muse, mutect2, varscan2
- SEMA6A | c.687A>C p.G229= | Silent (SNP) | VAF 17/212 reads (8%) | called by muse, mutect2
- ZNF267 | c.756C>G p.V252= | Silent (SNP) | VAF 12/96 reads (13%) | called by muse, mutect2, varscan2
- AC104771.1 | n.438G>T | RNA (SNP) | VAF 24/122 reads (20%) | called by muse, mutect2, varscan2
- ACTN1 | c.105+267T>G | Intron (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2, varscan2
- ACTR3 | c.*4432T>G | 3'UTR (SNP) | VAF 5/82 reads (6%) | called by muse, mutect2
- ADAM19 | c.*63T>C | 3'UTR (SNP) | VAF 13/83 reads (16%) | called by muse, mutect2, varscan2
- ATP10B | c.*1385G>T | 3'UTR (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2, varscan2
- CAPS2 | c.1670-1147A>C | Intron (SNP) | VAF 81/193 reads (42%) | called by muse, mutect2, varscan2
- CCDC6 | c.*1344G>A | 3'UTR (SNP) | VAF 16/74 reads (22%) | called by muse, mutect2, varscan2
- COL21A1 | c.*923A>G | 3'UTR (SNP) | VAF 44/112 reads (39%) | called by muse, mutect2, varscan2
- DLX4 | c.*330C>T | 3'UTR (SNP) | VAF 32/96 reads (33%) | called by muse, mutect2, varscan2
- DOCK1 | c.1059-46C>T | Intron (SNP) | VAF 20/64 reads (31%) | catalogued as rs1387795843; called by muse, mutect2, varscan2
- EDEM1 | c.-29A>T | 5'UTR (SNP) | VAF 19/42 reads (45%) | called by muse, varscan2
- F3 | c.*648C>T | 3'UTR (SNP) | VAF 31/64 reads (48%) | catalogued as rs141977136; called by muse, mutect2, varscan2
- FNBP1 | c.*2985T>C | 3'UTR (SNP) | VAF 30/72 reads (42%) | called by muse, mutect2, varscan2
- FXYD6-FXYD2 | c.259+6038C>A | Intron (SNP) | VAF 29/122 reads (24%) | called by muse, mutect2, varscan2
- GPR173 | c.*1786G>A | 3'UTR (SNP) | VAF 9/36 reads (25%) | called by muse, varscan2
- H4C9 | c.*15C>G | 3'UTR (SNP) | VAF 40/134 reads (30%) | called by muse, mutect2, varscan2
- HAPLN1 | c.*2995T>A | 3'UTR (SNP) | VAF 14/67 reads (21%) | called by muse, mutect2, varscan2
- HEPH | c.-350C>T | 5'UTR (SNP) | VAF 10/61 reads (16%) | called by muse, mutect2, varscan2
- HHIP | c.*2056T>G | 3'UTR (SNP) | VAF 33/76 reads (43%) | called by muse, mutect2, varscan2
- HMGA2 | c.249+4048G>A | Intron (SNP) | VAF 143/444 reads (32%) | called by muse, mutect2, varscan2
- INSYN1 | c.*132A>G | 3'UTR (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
- IREB2 | c.1195+155A>G | Intron (SNP) | VAF 39/100 reads (39%) | called by muse, mutect2, varscan2
- KATNAL1 | c.*613C>T | 3'UTR (SNP) | VAF 31/81 reads (38%) | catalogued as rs758485779; called by muse, mutect2
- KCNAB2 | c.804+52C>T | Intron (SNP) | VAF 27/85 reads (32%) | catalogued as rs371802598; called by muse, mutect2, varscan2
- LSM8 | c.*377C>T | 3'UTR (SNP) | VAF 9/90 reads (10%) | called by muse, mutect2
- LZTS1 | c.*2252A>G | 3'UTR (SNP) | VAF 66/159 reads (42%) | called by muse, mutect2, varscan2
- MAN1A2 | c.*25C>T | 3'UTR (SNP) | VAF 43/390 reads (11%) | called by muse, mutect2, varscan2
- MDM2 | c.*3258A>T | 3'UTR (SNP) | VAF 10/146 reads (7%) | catalogued as rs1310776678, COSV50700625; called by muse, mutect2
- MPI | c.144+71G>A | Intron (SNP) | VAF 15/96 reads (16%) | called by muse, mutect2, varscan2
- MPZL3 | c.*2832T>C | 3'UTR (SNP) | VAF 6/93 reads (6%) | catalogued as rs1173621736; called by muse, mutect2
- MYL2 | c.-47C>T | 5'UTR (SNP) | VAF 130/320 reads (41%) | catalogued as rs771537704, COSV99960546; called by muse, mutect2, varscan2
- OBI1 | c.*1040A>C | 3'UTR (SNP) | VAF 13/177 reads (7%) | called by muse, mutect2
- P4HA2 | c.1538-29A>T | Intron (SNP) | VAF 101/274 reads (37%) | called by muse, mutect2, varscan2
- PCDH10 | c.*43A>T | 3'UTR (SNP) | VAF 49/614 reads (8%) | catalogued as COSV52086715; called by muse, mutect2
- PCSK7 | c.*1213G>C | 3'UTR (SNP) | VAF 7/34 reads (21%) | called by mutect2, varscan2
- PIGX | c.*1505G>A | 3'UTR (SNP) | VAF 33/95 reads (35%) | called by muse, mutect2, varscan2
- PLCXD3 | c.*3746A>C | 3'UTR (SNP) | VAF 32/68 reads (47%) | called by muse, mutect2, varscan2
- POLD3 | c.*1191A>G | 3'UTR (SNP) | VAF 10/87 reads (11%) | called by muse, mutect2, varscan2
- PPIAP15 | chr3:109476733 A>T | 5'Flank (SNP) | VAF 17/74 reads (23%) | called by muse, mutect2, varscan2
- PUDP | c.*928G>T | 3'UTR (SNP) | VAF 12/60 reads (20%) | called by muse, mutect2, varscan2
- RIT2 | c.-9T>C | 5'UTR (SNP) | VAF 28/187 reads (15%) | called by muse, mutect2, varscan2
- RNMT | c.*4438T>G | 3'UTR (SNP) | VAF 12/94 reads (13%) | called by muse, mutect2, varscan2
- RYR2 | c.14151+49G>C | Intron (SNP) | VAF 12/98 reads (12%) | called by muse, mutect2, varscan2
- SLC25A22 | c.*431C>A | 3'UTR (SNP) | VAF 27/113 reads (24%) | called by muse, mutect2, varscan2
- SLC6A14 | c.*45T>G | 3'UTR (SNP) | VAF 32/139 reads (23%) | catalogued as COSV64140798; called by muse, mutect2, varscan2
- SLC7A2 | c.*2062T>C | 3'UTR (SNP) | VAF 21/98 reads (21%) | called by muse, mutect2, varscan2
- TECRL | c.*537C>T | 3'UTR (SNP) | VAF 46/282 reads (16%) | called by muse, mutect2, varscan2
- TRMT5 | c.*2514T>C | 3'UTR (SNP) | VAF 4/76 reads (5%) | called by muse, mutect2
- TRPC6 | c.-319C>T | 5'UTR (SNP) | VAF 19/132 reads (14%) | called by muse, mutect2, varscan2
- TUSC3 | chr8:15540225 C>A | 5'Flank (SNP) | VAF 23/133 reads (17%) | called by muse, mutect2, varscan2
- TXNDC5 | c.*720A>G | 3'UTR (SNP) | VAF 17/113 reads (15%) | called by muse, mutect2, varscan2
- UQCC3 | c.*126dup | 3'UTR (INS) | VAF 67/320 reads (21%) | called by mutect2, pindel, varscan2
- USP47 | c.*954T>A | 3'UTR (SNP) | VAF 14/84 reads (17%) | called by muse, mutect2, varscan2
- WDFY3 | c.*1064A>G | 3'UTR (SNP) | VAF 9/138 reads (7%) | called by muse, mutect2
- YWHAG | c.*2135T>G | 3'UTR (SNP) | VAF 10/129 reads (8%) | called by muse, mutect2
- ZFHX4 | c.3394+727C>A | Intron (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2
- ZNF2 | chr2:95183609 T>C | 3'Flank (SNP) | VAF 12/32 reads (38%) | called by mutect2, varscan2
